Somatic mutation profile of tumor specimen C3N-00294-02 (aliquot CPT0008450006) from CPTAC case C3N-00294, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 57.9 years (21,155 days).
Specimen C3N-00294-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db106a82-ac10-4a85-9bd9-5e7e56e92fc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00294-31 (Blood Derived Normal), aliquot CPT0008490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bbbfde3-dd0c-472b-bf46-090fed15b8f6

The open-access MAF lists 1,593 somatic variants for this specimen: 1,047 protein-altering or splice-affecting, 358 silent, 188 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 914, Silent 358, Nonsense Mutation 90, Intron 84, 5'UTR 34, 3'UTR 23, RNA 21, 5'Flank 18, Splice Region 15, Splice Site 15, 3'Flank 8, Frame Shift Del 5.

Variants (750 of 1,593; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JUN | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1184098204, COSV64664188, COSV64664376; called by muse, mutect2, varscan2
- KIF1A | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045655, COSV57486594; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 126/284 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 62/330 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 61/275 reads (22%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- TSC1 | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 22/202 reads (11%) | catalogued as rs397514871, CM104950, COSV53765939, COSV53770690; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.2194C>G p.Q732E (on ENST00000272895 / NM_173076.3; = p.Q414E on NM_015657.3) | Missense Mutation (SNP) | VAF 63/432 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV99787762; called by muse, mutect2, varscan2
- ABCA13 | c.5546C>A p.S1849Y | Missense Mutation (SNP) | VAF 55/558 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429459130; called by muse, mutect2, varscan2
- ABCA13 | c.8771C>G p.S2924* | Nonsense Mutation (SNP) | VAF 39/284 reads (14%) | catalogued as COSV71290693; called by muse, mutect2, varscan2
- ABCB6 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV54692609; called by muse, mutect2, varscan2
- ABHD1 | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1225805700; called by muse, mutect2, varscan2
- ABHD17A | c.861C>G p.I287M (on ENST00000292577 / NM_001130111.2; = p.I338M on NM_031213.4) | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1193835844; called by muse, mutect2, varscan2
- ACAD10 | c.2382G>C p.M794I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100563826; called by muse, mutect2, varscan2
- ACE | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99329473; called by muse, mutect2, varscan2
- ACSS1 | c.336C>G p.V112= | Splice Region (SNP) | VAF 20/93 reads (22%) | catalogued as COSV60218265; called by muse, mutect2, varscan2
- ACTR1B | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs201200377; called by muse, mutect2, varscan2
- ADAM12 | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 33/135 reads (24%) | catalogued as COSV100903658; called by muse, mutect2, varscan2
- ADAMTS12 | c.4587G>T p.Q1529H | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100710438; called by muse, mutect2, varscan2
- ADAMTS19 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as rs938750004, COSV50733429, COSV50802169; called by muse, mutect2, varscan2
- ADAMTS2 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1399773926; called by muse, mutect2, varscan2
- ADGRA3 | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460672477; called by muse, mutect2, varscan2
- AGBL1 | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV66855565; called by muse, mutect2, varscan2
- AKAP9 | c.3574C>G p.Q1192E | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV62353386; called by muse, mutect2, varscan2
- AKAP9 | c.6724G>C p.E2242Q (on ENST00000359028; = p.E2218Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62346060; called by muse, mutect2, varscan2
- AMBRA1 | c.1699C>T p.R567C (on ENST00000458649 / NM_001367468.1; = p.R477C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1214838212, COSV54059400; called by muse, mutect2, varscan2
- AMOTL2 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs777693609; called by muse, mutect2, varscan2
- ANKIB1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1222442609; called by muse, mutect2
- ANKRD36C | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1434257119, COSV101510937; called by muse, mutect2
- ANTXR2 | c.978G>T p.L326F | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100226954; called by muse, varscan2
- APBB3 | c.1036G>A p.E346K (on ENST00000357560 / NM_133173.2; = p.E353K on NM_006051.3) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.437); catalogued as COSV60052365; called by muse, mutect2, varscan2
- APC2 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV52018175; called by muse, varscan2
- AQP10 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV59245965; called by muse, mutect2
- AR | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 74/255 reads (29%) | catalogued as CM015295, COSV65953259; called by muse, mutect2, varscan2
- ARHGAP21 | c.2956G>C p.E986Q | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100256664; called by muse, mutect2, varscan2
- ARHGEF25 | c.1636C>A p.L546I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); catalogued as COSV54088202; called by muse, mutect2, varscan2
- ARHGEF4 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 75/360 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58124789; called by muse, mutect2, varscan2
- ARID1A | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV61374055; called by muse, mutect2, varscan2
- ARID1A | c.3387G>C p.K1129N | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100251470, COSV61377747; called by muse, mutect2, varscan2
- ASPHD1 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs866517331, COSV58101382; called by muse, mutect2
- ATG7 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.253); catalogued as rs774621794; called by muse, mutect2, varscan2
- ATM | c.6253G>C p.D2085H | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV99586747; called by muse, mutect2, varscan2
- ATP13A4 | c.2786C>G p.S929* | Nonsense Mutation (SNP) | VAF 54/240 reads (23%) | catalogued as COSV61319082; called by muse, varscan2
- ATP8B2 | c.1795C>G p.L599V (on ENST00000672630; = p.L566V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs566349693; called by muse, mutect2, varscan2
- B3GALT1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV59908505; called by muse, mutect2, varscan2
- B4GALT1 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs780658900, COSV65709115; called by muse, mutect2, varscan2
- BCAS1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 78/399 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs193016127; called by muse, mutect2, varscan2
- BDH1 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs201488968; called by muse, varscan2
- BDKRB1 | c.633C>G p.F211L | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53706382; called by muse, mutect2, varscan2
- BMT2 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as COSV51778182; called by muse, mutect2, varscan2
- BRWD3 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100955559; called by muse, mutect2, varscan2
- BUB1 | c.2743C>T p.H915Y | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762266309; called by muse, mutect2, varscan2
- C1orf174 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs1461782564; called by muse, mutect2, varscan2
- C2CD4A | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs1325634859; called by muse, mutect2, varscan2
- C6 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 78/542 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs779633819, COSV54713410; called by muse, mutect2, varscan2
- CA3 | c.235C>T p.L79= | Splice Region (SNP) | VAF 33/146 reads (23%) | catalogued as rs1431992785; called by muse, mutect2, varscan2
- CAND1 | c.2368C>T p.L790F | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV73389586; called by muse, mutect2, varscan2
- CANT1 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 128/567 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56606113; called by muse, mutect2, varscan2
- CCDC142 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.204); catalogued as COSV51777148; called by muse, mutect2, varscan2
- CCDC51 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.487); catalogued as COSV99602825; called by muse, mutect2
- CDK13 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.258); catalogued as rs1480119569, COSV99475896; called by muse, mutect2, varscan2
- CDR1 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.283); catalogued as rs759669598; called by muse, mutect2, varscan2
- CENPA | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs1392372965, COSV51983107; called by muse, mutect2, varscan2
- CENPI | c.317C>A p.S106* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV54501586; called by muse, mutect2, varscan2
- CFAP92 | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1305093484; called by muse, varscan2
- CHD1 | c.3658G>C p.E1220Q | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52341620; called by muse, mutect2, varscan2
- CHD4 | c.4528G>A p.E1510K (on ENST00000357008 / NM_001363606.2; = p.E1523K on NM_001273.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV58903579; called by muse, mutect2, varscan2
- CHD4 | c.2419G>A p.E807K (on ENST00000357008 / NM_001363606.2; = p.E820K on NM_001273.5) | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58913075; called by muse, mutect2, varscan2
- CHL1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs752032870, COSV56598659; called by muse, mutect2, varscan2
- CHMP3 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV55684997, COSV99806494; called by muse, mutect2, varscan2
- CHST8 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.577); catalogued as rs916046058, COSV52856983; called by muse, mutect2, varscan2
- CHUK | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64918791; called by muse, varscan2
- CLEC16A | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as COSV68501713; called by muse, mutect2, varscan2
- CLEC4G | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61003799; called by muse, mutect2, varscan2
- CNNM4 | c.1690C>G p.Q564E | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as CM090742; called by muse, mutect2, varscan2
- CNTRL | c.4486C>T p.Q1496* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as rs749891425; called by muse, mutect2, varscan2
- COL14A1 | c.1943C>G p.S648* | Nonsense Mutation (SNP) | VAF 29/172 reads (17%) | catalogued as COSV99918853; called by muse, mutect2, varscan2
- CORO1B | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs770094141; called by muse, mutect2, varscan2
- CORO6 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61471502; called by muse, mutect2, varscan2
- CPS1 | c.3608C>T p.S1203L | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149518280, CM114379; called by muse, varscan2
- CREB3L3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs748509446; called by muse, mutect2, varscan2
- CRLF2 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1361857498; called by muse, mutect2, varscan2
- CSMD3 | c.8756G>C p.R2919T (on ENST00000297405 / NM_001363185.1; = p.R2750T on NM_052900.3) | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52229105; called by muse, mutect2, varscan2
- CSPG4 | c.4022G>A p.G1341D | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.88); catalogued as rs775787859; called by muse, mutect2, varscan2
- CSPP1 | c.1394C>T p.S465L (on ENST00000676605; = p.S424L on NM_024790.6) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs750389579, COSV51591986; called by muse, mutect2, varscan2
- CTNNA2 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 80/185 reads (43%) | catalogued as COSV58169685; called by muse, mutect2, varscan2
- CTNND2 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 30/238 reads (13%) | catalogued as COSV58877865; called by muse, mutect2, varscan2
- CTU1 | c.354C>A p.Y118* | Nonsense Mutation (SNP) | VAF 50/205 reads (24%) | catalogued as rs1457193469, COSV70292834; called by muse, varscan2
- CUL3 | c.504G>C p.M168I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); catalogued as COSV52365383; called by muse, mutect2, varscan2
- CYP4F11 | c.1232G>C p.G411A | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99931022; called by muse, mutect2, varscan2
- CYP4F12 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.594); catalogued as rs189002430; called by muse, mutect2, varscan2
- DACH2 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); catalogued as COSV100913393; called by muse, mutect2, varscan2
- DDB1 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100074305; called by muse, mutect2, varscan2
- DENND4B | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748707602, COSV63408603; called by muse, mutect2
- DMXL1 | c.5995G>A p.D1999N | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV60717441; called by muse, mutect2, varscan2
- DNAH17 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV101103301; called by muse, mutect2, varscan2
- DNAH6 | c.7991C>G p.P2664R | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52875979; called by muse, mutect2, varscan2
- DNAH6 | c.8149G>C p.E2717Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as rs1217381038; called by muse, mutect2, varscan2
- DNAJC13 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99607080; called by muse, mutect2, varscan2
- DOCK8 | c.3391-1G>A p.X1131_splice | Splice Site (SNP) | VAF 60/344 reads (17%) | catalogued as COSV66618192; called by muse, mutect2, varscan2
- DOK5 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 28/179 reads (16%) | catalogued as rs148201917; called by muse, mutect2, varscan2
- DPM1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 99/418 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV99724522; called by muse, mutect2, varscan2
- DR1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as rs780919729; called by muse, mutect2, varscan2
- DROSHA | c.3819G>C p.R1273S | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60779554; called by muse, mutect2, varscan2
- DROSHA | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.088); catalogued as rs1232457396; called by muse, varscan2
- DUOXA2 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 48/476 reads (10%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.815); catalogued as rs1371612087; called by muse, mutect2
- DUS4L-BCAP29 | c.1378G>C p.D460H | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1240841169, COSV50052625; called by muse, mutect2
- DYNC1H1 | c.12076G>T p.D4026Y | Missense Mutation (SNP) | VAF 126/342 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64140358; called by muse, mutect2, varscan2
- E2F1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | catalogued as COSV100594057; called by muse, mutect2, varscan2
- EBF1 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs1177307849; called by muse, mutect2
- EBP | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as CM086600, COSV99339332; called by muse, mutect2, varscan2
- EFCAB5 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs941407425; called by muse, mutect2, varscan2
- EGR3 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs377538095; called by muse, mutect2, varscan2
- ELMO1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1174488092, COSV60296526; called by muse, mutect2, varscan2
- ELN | c.1324C>G p.Q442E | Missense Mutation (SNP) | VAF 64/656 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); catalogued as CM970433, COSV52715007; called by muse, mutect2
- EME1 | c.1446G>C p.W482C | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1015704307; called by muse, mutect2, varscan2
- ENG | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.198); catalogued as rs1229006135; called by muse, mutect2, varscan2
- EP300 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 81/429 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99609114; called by muse, mutect2, varscan2
- ETV3 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1223278264, COSV63864584; called by muse, varscan2
- ETV4 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs776306922, COSV100081499, COSV60043769; called by muse, mutect2, varscan2
- EYS | c.4764G>A p.M1588I | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV58200429; called by muse, mutect2, varscan2
- F8 | c.5465G>C p.R1822T | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as CM125452; called by muse, varscan2
- FABP9 | c.349-1G>C p.X117_splice | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as rs768459707; called by muse, mutect2, varscan2
- FAM135B | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV52704878; called by muse, mutect2, varscan2
- FAM193A | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV61192892; called by muse, varscan2
- FAM193B | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100286882; called by muse, mutect2, varscan2
- FAM193B | c.963G>C p.K321N | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779194989; called by muse, mutect2, varscan2
- FAM20C | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 59/551 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.413); catalogued as rs1242978606; called by muse, mutect2, varscan2
- FAM81A | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 71/363 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as rs1367636485; called by muse, mutect2, varscan2
- FAM83C | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs951918774, COSV65582912; called by muse, mutect2, varscan2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FBRSL1 | c.1703A>G p.Q568R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1017782057; called by muse, mutect2, varscan2
- FBXO3 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as COSV55764941; called by muse, mutect2, varscan2
- FCER1A | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 20/158 reads (13%) | catalogued as COSV63666616; called by muse, mutect2, varscan2
- FEN1 | c.921C>G p.I307M | Missense Mutation (SNP) | VAF 82/479 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs772603170; called by muse, mutect2, varscan2
- FERMT3 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1374970885; called by muse, mutect2, varscan2
- FEZ2 | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs982575915; called by muse, mutect2
- FGD2 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV51463072; called by muse, mutect2, varscan2
- FRMD1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.528); catalogued as rs1241837386, COSV51962418; called by muse, mutect2
- GABRR3 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1489335840; called by muse, mutect2, varscan2
- GEMIN5 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53566077; called by muse, mutect2, varscan2
- GJA8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs781915687, COSV53788224; called by muse, mutect2
- GPD2 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186775701; called by muse, mutect2, varscan2
- GPNMB | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 75/517 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1236146268, COSV51698036, COSV51700439; called by muse, mutect2, varscan2
- GPR50 | c.1784C>A p.T595N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV54438769; called by muse, mutect2, varscan2
- GRIK4 | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755023411; called by muse, mutect2, varscan2
- GRXCR1 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101295690, COSV67674123; called by muse, mutect2, varscan2
- GTF3C1 | c.3554C>T p.S1185F | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs973079409, COSV100649665; called by muse, mutect2, varscan2
- H2BC1 | c.173C>G p.S58W | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51237068; called by muse, mutect2, varscan2
- H2BU1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV100797249; called by muse, mutect2, varscan2
- H3C2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs753823527, COSV52518737; called by muse, mutect2, varscan2
- HCN1 | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 214/617 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100301972; called by muse, mutect2, varscan2
- HEATR1 | c.1449G>C p.L483F | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63979781; called by muse, mutect2
- HELZ | c.2642A>G p.Y881C | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62380813; called by muse, varscan2
- HGFAC | c.1182C>A p.C394* | Nonsense Mutation (SNP) | VAF 97/219 reads (44%) | catalogued as rs574069730; called by muse, mutect2, varscan2
- HMCN1 | c.2124G>C p.Q708H | Missense Mutation (SNP) | VAF 66/543 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); catalogued as rs769461980; called by muse, mutect2, varscan2
- HMCN1 | c.2510G>A p.R837K | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54947881; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.259G>C p.D87H (on ENST00000354667 / NM_031243.3; = p.D75H on NM_002137.4) | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61159727; called by muse, mutect2, varscan2
- HOXD4 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs935402889; called by muse, mutect2, varscan2
- HRNR | c.2849G>C p.G950A | Missense Mutation (SNP) | VAF 123/1064 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs755677565, COSV64261713; called by muse, mutect2, varscan2
- HS6ST1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 80/553 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as rs983617593; called by muse, mutect2, varscan2
- HSF1 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1380436858, COSV60047480; called by muse, mutect2, varscan2
- HSPA12A | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100979715; called by muse, mutect2, varscan2
- HSPA14 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as rs1408033023; called by muse, mutect2, varscan2
- HYOU1 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV101345656; called by muse, mutect2, varscan2
- IFNA16 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV66510056; called by muse, mutect2, varscan2
- IFNL3 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs151331735, COSV101308017; called by muse, mutect2, varscan2
- IGHMBP2 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs774375391; called by muse, mutect2, varscan2
- IL17F | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 70/365 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as rs1173562555, COSV100277222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INSL4 | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1206550366, COSV53329700; called by muse, mutect2, varscan2
- ITPRIP | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs751175958, COSV53390558; called by muse, mutect2, varscan2
- JADE2 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV50927131; called by muse, mutect2, varscan2
- JMJD4 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs148842395; called by muse, mutect2, varscan2
- KAT6B | c.1829G>C p.R610T | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.991); catalogued as COSV99767068; called by muse, mutect2, varscan2
- KCNA2 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs756214647, COSV60369282; called by muse, mutect2, varscan2
- KCNG4 | c.1516G>C p.D506H | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.293); catalogued as COSV57583836; called by muse, mutect2, varscan2
- KDM5B | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1277190443; called by muse, mutect2, varscan2
- KIF13B | c.4961C>T p.S1654L | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as rs1455836285; called by muse, mutect2, varscan2
- KIF26B | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1167184416; called by muse, mutect2
- KLC4 | c.1503C>G p.I501M | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.316); catalogued as COSV99432092; called by muse, mutect2, varscan2
- KLF15 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56180492; called by muse, mutect2, varscan2
- KLF5 | c.1165C>A p.H389N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66614500; called by muse, mutect2, varscan2
- KNTC1 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV61082411; called by muse, mutect2, varscan2
- LARP6 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs1283174806; called by muse, mutect2, varscan2
- LGR5 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57004672; called by muse, mutect2, varscan2
- LLGL2 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV51359845; called by muse, mutect2
- LLGL2 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs541727805; called by muse, varscan2
- LNX1 | c.523G>C p.D175H (on ENST00000263925 / NM_001126328.3; = p.D79H on NM_032622.2) | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV55787138; called by muse, mutect2, varscan2
- LONP1 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748047263, COSV62262071, COSV62262525; called by muse, mutect2, varscan2
- LRP1B | c.4995G>A p.W1665* | Nonsense Mutation (SNP) | VAF 18/148 reads (12%) | catalogued as COSV67229064; called by muse, mutect2, varscan2
- LRRC7 | c.697G>A p.E233K (on ENST00000651989 / NM_001370785.2; = p.E200K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV50651939; called by muse, mutect2, varscan2
- LSS | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs988009687; called by muse, mutect2, varscan2
- MAGEF1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775205261; called by muse, mutect2, varscan2
- MAP10 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs374691511; called by muse, mutect2, varscan2
- MAP3K19 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1023047237, COSV59637237; called by muse, mutect2, varscan2
- MAP4K1 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV67712710; called by muse, varscan2
- MAP4K4 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.091); catalogued as rs772128002, COSV56340169; called by muse, mutect2, varscan2
- MARVELD2 | c.1486C>G p.H496D | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV57782715; called by muse, mutect2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MBD5 | c.2001G>T p.L667F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.391); catalogued as COSV68698430; called by muse, mutect2, varscan2
- MCCC1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55610007; called by muse, mutect2, varscan2
- MCL1 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 77/556 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV57191352; called by muse, mutect2, varscan2
- MGRN1 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs766556602, COSV99273706, COSV99274472; called by muse, mutect2, varscan2
- MKRN3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs766172042, COSV100091125; called by muse, mutect2, varscan2
- MMP24 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55768187; called by muse, mutect2, varscan2
- MOSPD2 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs775308720; called by muse, mutect2, varscan2
- MROH8 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs998769239; called by muse, mutect2, varscan2
- MRPL36 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321917312; called by muse, mutect2, varscan2
- MRPS26 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775888819; called by muse, mutect2, varscan2
- MS4A1 | c.450G>C p.E150D | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as rs1216561132; called by muse, mutect2, varscan2
- MTERF2 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as rs1201710577; called by muse, mutect2, varscan2
- MTF1 | c.1107C>G p.I369M | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV65989228; called by muse, mutect2, varscan2
- MUC16 | c.8920G>T p.E2974* | Nonsense Mutation (SNP) | VAF 41/205 reads (20%) | catalogued as COSV67477786; called by muse, mutect2, varscan2
- MUC4 | c.5665C>T p.L1889F | Missense Mutation (SNP) | VAF 82/674 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as rs1241337630, COSV100640426; called by muse, varscan2
- MUC5AC | c.14489C>T p.T4830M | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as rs766248850; called by muse, mutect2, varscan2
- MYCBP2 | c.1847C>G p.S616C (on ENST00000357337; = p.S654C on NM_015057.5) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs377565885; called by muse, mutect2, varscan2
- MYH3 | c.3675C>G p.F1225L | Missense Mutation (SNP) | VAF 23/510 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99877797; called by muse, mutect2
- MYO18B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs751222865, COSV59126310, COSV59129122; called by muse, mutect2, varscan2
- MYO18B | c.3329C>A p.S1110* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | catalogued as COSV100123513, COSV59132236; called by muse, mutect2, varscan2
- MYO7A | c.3266C>A p.A1089D | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.356); catalogued as rs1555085586; called by muse, mutect2, varscan2
- MYO9B | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.363); catalogued as COSV101261208, COSV68282552; called by muse, mutect2, varscan2
- MYPOP | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV59135090; called by muse, mutect2, varscan2
- MZF1 | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs371153551, COSV53041187; called by muse, mutect2, varscan2
- N4BP2 | c.1261C>G p.Q421E | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV54701993; called by muse, mutect2, varscan2
- NAA30 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1224102042, COSV53648467; called by muse, mutect2, varscan2
- NCAM1 | c.2411G>A p.G804E (on ENST00000316851 / NM_181351.5; = p.G794E on NM_000615.7) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs782380026; called by muse, mutect2, varscan2
- NDFIP2 | c.714C>T p.F238= | Splice Region (SNP) | VAF 27/134 reads (20%) | catalogued as rs1245504068; called by muse, mutect2, varscan2
- NEFH | c.819G>C p.E273D | Missense Mutation (SNP) | VAF 87/411 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.569); catalogued as rs917756240, COSV60220162, COSV60220757; called by muse, mutect2, varscan2
- NF1 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV62195017; called by muse, mutect2, varscan2
- NFATC3 | c.1900C>G p.L634V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as COSV60472067, COSV60479879; called by muse, mutect2, varscan2
- NHEJ1 | c.351C>G p.F117L | Missense Mutation (SNP) | VAF 40/591 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1249067213, COSV55405622; ClinVar: uncertain significance; called by muse, mutect2
- NIFK | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV53534702; called by muse, mutect2, varscan2
- NLRP1 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs201808181; called by muse, mutect2, varscan2
- NLRP9 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV100243293; called by muse, mutect2, varscan2
- NOP2 | c.895G>C p.E299Q (on ENST00000322166 / NM_001258308.2; = p.E295Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV59110448; called by muse, mutect2, varscan2
- NPHP4 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773309269, COSV65397986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.2947C>T p.L983F | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58436353, COSV58440546; called by muse, mutect2
- NRXN3 | c.2823C>G p.I941M (on ENST00000335750 / NM_001330195.2; = p.I568M on NM_004796.6) | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as COSV59730982; called by muse, mutect2, varscan2
- NSUN4 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs752512220; called by muse, mutect2, varscan2
- NUGGC | c.1605C>G p.C535W | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as rs759541966; called by muse, mutect2, varscan2
- OBSCN | c.4189C>T p.R1397* | Nonsense Mutation (SNP) | VAF 33/504 reads (7%) | catalogued as rs1158912574, COSV52746867; called by muse, mutect2
- OR10K2 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as rs748681939; called by muse, mutect2, varscan2
- OR2A5 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV68738894; called by muse, mutect2
- OR2T35 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 274/1527 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs767405322; called by muse, mutect2
- OR8G1 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV58382986; called by muse, mutect2, varscan2
- OR8J1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV57319869; called by muse, mutect2, varscan2
- OTUD1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1241086090; called by muse, mutect2, varscan2
- PALM3 | c.1756G>A p.E586K (on ENST00000340790; = p.E601K on NM_001145028.2) | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV54601832; called by muse, varscan2
- PALM3 | c.1660G>A p.E554K (on ENST00000340790; = p.E569K on NM_001145028.2) | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1306403991; called by muse, varscan2
- PARVA | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58518753; called by muse, mutect2, varscan2
- PAX6 | c.532C>G p.Q178E | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as CM1110705; called by muse, mutect2, varscan2
- PCDH11Y | c.1930G>A p.E644K (on ENST00000400457 / NM_032973.2; = p.E633K on NM_032971.3) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.14); catalogued as rs765993869; called by muse, mutect2, varscan2
- PCDHGC3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452697214, COSV52744109; called by muse, mutect2, varscan2
- PEG3 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs747261591, COSV99687238; called by muse, mutect2, varscan2
- PGK2 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1410151932, COSV59162804; called by muse, mutect2
- PHACTR2 | c.176C>G p.S59W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs931412517; called by muse, mutect2, varscan2
- PIAS4 | c.483G>C p.E161D | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV53679922; called by muse, mutect2, varscan2
- PIH1D2 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.084); catalogued as rs940655083, COSV54776852, COSV99735636; called by muse, mutect2
- PIK3C2G | c.192dup p.V65Cfs*16 | Frame Shift Ins (INS) | VAF 25/170 reads (15%) | catalogued as rs1565550462; called by pindel, varscan2
- PIK3C2G | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 56/358 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs1291982801, COSV56810157; called by muse, varscan2
- PINK1 | c.1319G>C p.G440A | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM085640; called by muse, mutect2, varscan2
- PKDREJ | c.1691G>C p.G564A | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53548651; called by muse, mutect2, varscan2
- PLEC | c.12750G>C p.Q4250H (on ENST00000322810 / NM_201380.4; = p.Q4140H on NM_000445.5) | Missense Mutation (SNP) | VAF 118/548 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs782778503; called by muse, mutect2, varscan2
- PLXNA3 | c.2496G>C p.Q832H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.404); catalogued as COSV100860026; called by muse, mutect2, varscan2
- PLXNC1 | c.2641C>G p.L881V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.458); catalogued as rs765489640; called by muse, mutect2, varscan2
- PMEPA1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.124); catalogued as rs1448148442, COSV99671628; called by muse, mutect2, varscan2
- PML | c.772C>G p.H258D | Missense Mutation (SNP) | VAF 20/385 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV51450070, COSV51455105; called by muse, mutect2
- PNPLA1 | c.1465G>T p.V489L (on ENST00000394571 / NM_001374623.1; = p.V394L on NM_173676.2) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV57233249; called by muse, mutect2, varscan2
- PNPLA8 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV57552358, COSV57554440; called by muse, mutect2, varscan2
- POLD1 | c.1776-5C>G | Splice Region (SNP) | VAF 28/119 reads (24%) | catalogued as COSV70957797; called by muse, mutect2, varscan2
- POLD3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as rs1250269795; called by muse, varscan2
- POLR1A | c.3658G>A p.G1220R | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461382886, COSV55691353; called by muse, mutect2, varscan2
- POLR3A | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100965836; called by muse, mutect2, varscan2
- PPFIA3 | c.3553G>C p.D1185H | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV53255487, COSV53256391; called by muse, mutect2, varscan2
- PPP1R3A | c.2566C>G p.Q856E | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV52887278, COSV52887524, COSV52894554; called by muse, mutect2, varscan2
- PPP2R3A | c.3115C>G p.L1039V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs913181251; called by muse, mutect2, varscan2
- PPP3R1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs1484879018; called by muse, mutect2, varscan2
- PRAG1 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV58162139; called by muse, mutect2, varscan2
- PRDM9 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 86/718 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as COSV57008999; called by muse, varscan2
- PRELID2 | c.493C>T p.R165* (on ENST00000334744 / NM_182960.4; = p.R124* on NM_138492.6) | Nonsense Mutation (SNP) | VAF 38/169 reads (22%) | catalogued as rs375685870; called by muse, mutect2, varscan2
- PRKCB | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57780160; called by muse, varscan2
- PRKCQ | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99576103; called by muse, mutect2, varscan2
- PRR11 | c.228G>C p.W76C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs541636774; called by muse, mutect2, varscan2
- PRUNE2 | c.5434G>T p.E1812* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV65037525; called by muse, mutect2, varscan2
- PSMD1 | c.942+1G>A p.X314_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | catalogued as COSV100433364; called by muse, mutect2
- PSMD12 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs761043799; called by muse, mutect2, varscan2
- PSME4 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV66366195; called by muse, mutect2, varscan2
- PTH2R | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143390240, COSV55919295; called by mutect2, varscan2
- PTPRC | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as CD012009; called by muse, mutect2, varscan2
- PTPRC | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 104/195 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV61408140; called by muse, mutect2, varscan2
- RBFOX1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.069); catalogued as rs527782263, COSV60944925; called by muse, mutect2, varscan2
- RCC1L | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.374); catalogued as rs781910319; called by muse, mutect2, varscan2
- RERGL | c.385C>G p.H129D | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57462212; called by muse, mutect2, varscan2
- RGL1 | c.1869C>G p.I623M (on ENST00000360851 / NM_001297672.2; = p.I658M on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/484 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1456441085; called by muse, mutect2, varscan2
- RGS7 | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV100469052, COSV58535852, COSV58545518; called by muse, mutect2, varscan2
- RICTOR | c.2530G>A p.E844K | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57123279; called by muse, mutect2, varscan2
- RNF133 | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs777199054; called by muse, mutect2
- RNF187 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1030185199, COSV59959857, COSV59960193; called by muse, varscan2
- RNF2 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV62279838; called by muse, mutect2, varscan2
- RP1 | c.4073C>T p.S1358L | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55114117; called by muse, mutect2, varscan2
- RPE | c.506C>T p.S169F (on ENST00000359429 / NM_001318926.1; = p.S119F on NM_006916.2) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1372110583; called by muse, mutect2, varscan2
- RPS21 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99652913; called by muse, mutect2, varscan2
- RREB1 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 26/134 reads (19%) | catalogued as COSV58565678; called by muse, mutect2, varscan2
- RSPH10B | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as rs1425238873; called by muse, mutect2, varscan2
- RXRG | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as rs1416940954, COSV63233254; called by muse, mutect2, varscan2
- RYR2 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63675798; called by muse, varscan2
- RYR3 | c.12349G>A p.E4117K (on ENST00000389232; = p.E4118K on NM_001036.6) | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV66803492; called by muse, mutect2, varscan2
- SBNO2 | c.3883G>A p.D1295N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.078); catalogued as rs1428839243; called by muse, mutect2
- SCART1 | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs892189095; called by muse, mutect2, varscan2
- SCN1A | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.478); catalogued as COSV57684295; called by muse, mutect2, varscan2
- SCN3A | c.2749G>C p.D917H | Missense Mutation (SNP) | VAF 83/587 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV99326167; called by muse, mutect2, varscan2
- SCNN1D | c.611G>C p.R204T (on ENST00000338555; = p.R368T on NM_001130413.4) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs1436040833, COSV57639869; called by muse, mutect2, varscan2
- SEMA3C | c.1895C>G p.S632C | Missense Mutation (SNP) | VAF 66/417 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757381855; called by muse, mutect2, varscan2
- SEZ6L2 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.092); catalogued as COSV100435933; called by muse, mutect2, varscan2
- SEZ6L2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs763342798, COSV58100396; called by muse, mutect2, varscan2
- SFSWAP | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55521016; called by muse, mutect2, varscan2
- SHANK1 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | catalogued as COSV53247657; called by muse, mutect2, varscan2
- SHISA7 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1366696970; called by muse, mutect2
- SHROOM4 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1557255450, COSV56799157, COSV99173007; called by muse, mutect2, varscan2
- SIGLEC14 | c.1011G>A p.Q337= | Splice Region (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99707421; called by muse, mutect2, varscan2
- SIGLEC8 | c.996C>A p.N332K | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58473511; called by muse, mutect2, varscan2
- SIGLECL1 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1336930479; called by muse, mutect2
- SIPA1L2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53394570, COSV99479889; called by muse, mutect2, varscan2
- SIRT5 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.267); catalogued as COSV63079873, COSV63080493; called by muse, mutect2, varscan2
- SKIV2L | c.1191C>G p.I397M | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV64811500; called by muse, mutect2, varscan2
- SLC10A2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs200038147, COSV55360654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC7A5 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 67/385 reads (17%) | catalogued as rs768660500; called by muse, mutect2, varscan2
- SLC9A3 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1560981486; called by muse, mutect2, varscan2
- SLFN13 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs753022696; called by muse, varscan2
- SMARCAD1 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs1378204418; called by muse, mutect2, varscan2
- SMC2 | c.2380G>T p.A794S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53963940; called by muse, mutect2, varscan2
- SMC3 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62421101; called by muse, mutect2, varscan2
- SMG7 | c.1223C>G p.S408* | Nonsense Mutation (SNP) | VAF 21/148 reads (14%) | catalogued as COSV100750044; called by muse, mutect2, varscan2
- SORCS3 | c.3262C>T p.L1088F | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63829632; called by muse, mutect2, varscan2
- SOX4 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 72/312 reads (23%) | catalogued as COSV55193191; called by muse, mutect2, varscan2
- SP140 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100613804; called by muse, varscan2
- SPC24 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV70607061, COSV70607286; called by muse, varscan2
- SPIRE2 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1480027511; called by muse, mutect2, varscan2
- SPRY1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV59337986; called by muse, mutect2, varscan2
- SPTA1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 72/569 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); catalogued as COSV63758718; called by muse, mutect2, varscan2
- SPTA1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 83/630 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs367689703; called by muse, mutect2, varscan2
- SPTBN1 | c.6196G>A p.A2066T | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.277); catalogued as rs1487383977; called by muse, mutect2, varscan2
- SRCAP | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV99351069; called by muse, mutect2, varscan2
- STIL | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as rs1557710415; called by muse, mutect2, varscan2
- STS | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as rs368690119; called by muse, mutect2, varscan2
- STX11 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs762230591, COSV99055961; called by muse, mutect2, varscan2
- STXBP2 | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 300/604 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM106813; called by muse, mutect2, varscan2
- SV2C | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs761310792, COSV59216339; called by muse, mutect2, varscan2
- SWAP70 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100014029; called by muse, mutect2, varscan2
- SYNPO | c.1720C>G p.L574V (on ENST00000394243 / NM_001166208.2; = p.L330V on NM_007286.6) | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV56940251; called by muse, mutect2, varscan2
- SYT12 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as COSV67355283; called by muse, mutect2, varscan2
- TAGLN3 | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 27/141 reads (19%) | catalogued as rs1218035526, COSV56329823; called by muse, mutect2, varscan2
- TAP1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs773916016; called by muse, mutect2, varscan2
- TARS1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV99035566; called by muse, mutect2, varscan2
- TASOR2 | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1415026841; called by muse, mutect2
- TCF7L2 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV60501426, COSV60511336; called by muse, mutect2, varscan2
- TDRD6 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.423); catalogued as rs1013467226; called by muse, mutect2, varscan2
- TDRD6 | c.4006G>C p.E1336Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60178043; called by muse, mutect2, varscan2
- TENM2 | c.7840G>A p.E2614K (on ENST00000518659 / NM_001122679.2; = p.E2375K on NM_001080428.3) | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs781581501, COSV69129045; called by muse, mutect2, varscan2
- TERF1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV52579950; called by muse, mutect2, varscan2
- THSD7A | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs1188725285; called by muse, mutect2, varscan2
- TICRR | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs751578978; called by muse, mutect2, varscan2
- TIGD5 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1211583093, COSV57817610; called by muse, mutect2, varscan2
- TMEM255B | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.288); catalogued as COSV64714662; called by muse, mutect2, varscan2
- TMEM40 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.085); catalogued as rs764930665, COSV53148048; called by muse, mutect2, varscan2
- TMPRSS3 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.155); catalogued as rs1240567443; called by muse, mutect2, varscan2
- TNRC18 | c.2708C>G p.S903* | Nonsense Mutation (SNP) | VAF 29/229 reads (13%) | catalogued as COSV68163762; called by muse, mutect2, varscan2
- TRADD | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs763349245, COSV61460081; called by muse, mutect2, varscan2
- TRAV22 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs769353647; called by muse, mutect2, varscan2
- TRAV40 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as rs1397874177; called by muse, mutect2, varscan2
- TRIM56 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs1369894623; called by muse, mutect2, varscan2
- TRIM7 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as rs1470412474; called by muse, mutect2, varscan2
- TRPV5 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 38/374 reads (10%) | catalogued as rs1350410887, COSV54687679; called by muse, mutect2
- TSGA13 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.482); catalogued as COSV58405158, COSV58406330; called by muse, mutect2, varscan2
- TTN | c.11803C>G p.L3935V (on ENST00000591111; = p.L3889V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV60250223; called by muse, mutect2, varscan2
- TUBA1C | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99988805; called by muse, mutect2, varscan2
- TUBGCP5 | c.768G>T p.L256F | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as rs1221268915; called by muse, mutect2, varscan2
- TWIST2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.634); catalogued as rs1379633566; called by mutect2, varscan2
- UBE4A | c.309G>C p.L103F | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs201069795; called by muse, mutect2, varscan2
- UBR3 | c.2391G>A p.M797I | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55857967; called by muse, mutect2
- UIMC1 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101022050; called by muse, mutect2, varscan2
- UNC13C | c.3077G>C p.G1026A | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as COSV99510073; called by muse, mutect2, varscan2
- UNC79 | c.5170G>A p.E1724K (on ENST00000393151 / NM_001346218.2; = p.E1547K on NM_020818.5) | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.038); catalogued as rs761093792, COSV56419507; called by muse, mutect2, varscan2
- UNC80 | c.9100G>A p.E3034K | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs780309223, COSV55892541; called by muse, mutect2, varscan2
- UQCRQ | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as COSV51527150; called by muse, mutect2, varscan2
- USH2A | c.15532G>A p.E5178K | Missense Mutation (SNP) | VAF 53/499 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV99379783; called by muse, mutect2, varscan2
- USH2A | c.8519C>T p.S2840F | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56372003; called by muse, mutect2, varscan2
- USH2A | c.4789G>A p.D1597N | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56431208; called by muse, mutect2, varscan2
- USP34 | c.8755G>C p.E2919Q | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs543319914; called by muse, mutect2, varscan2
- USP34 | c.6450G>C p.L2150F | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99063693; called by muse, mutect2, varscan2
- USP34 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV68402093, COSV68404411; called by muse, mutect2, varscan2
- USP38 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100189370; called by muse, mutect2, varscan2
- UTP18 | c.764C>G p.S255* | Nonsense Mutation (SNP) | VAF 27/209 reads (13%) | catalogued as COSV56583122, COSV56583641, COSV56585037; called by muse, mutect2, varscan2
- VGLL3 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as rs1388532002, COSV101051877, COSV101051922; called by muse, mutect2, varscan2
- VPS13D | c.12901G>A p.E4301K | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV50638022; called by muse, mutect2, varscan2
- VPS41 | c.247-1G>T p.X83_splice | Splice Site (SNP) | VAF 52/182 reads (29%) | catalogued as COSV99730620; called by mutect2, varscan2
- WAC | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV61566735; called by muse, varscan2
- WDCP | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54592404; called by muse, mutect2, varscan2
- WFDC9 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1449526632; called by muse, mutect2, varscan2
- XIRP2 | c.689C>T p.S230L (on ENST00000628543; = p.S405L on NM_152381.6) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV54685883; called by muse, varscan2
- XYLB | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 36/167 reads (22%) | catalogued as rs573319439; called by muse, mutect2, varscan2
- YEATS2 | c.621G>C p.K207N | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV59363184; called by muse, mutect2, varscan2
- ZAN | c.8329G>A p.V2777M | Missense Mutation (SNP) | VAF 41/461 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs1054763836; called by muse, mutect2
- ZC3H13 | c.3178G>C p.E1060Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV54451660; called by muse, mutect2, varscan2
- ZFYVE16 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1313450999; called by muse, varscan2
- ZNF257 | c.913C>G p.Q305E | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.425); catalogued as rs1348976473, COSV101448118, COSV71306944; called by muse, mutect2, varscan2
- ZNF418 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV68676475; called by muse, varscan2
- ZNF443 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.155); catalogued as rs1191248159, COSV56890455; called by muse, mutect2, varscan2
- ZNF569 | c.30C>G p.F10L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs199661417; called by muse, mutect2
- ZNF57 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60983159; called by muse, mutect2, varscan2
- ZNF699 | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1420867898; called by muse, mutect2, varscan2
- ZNF785 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV67876247; called by muse, mutect2, varscan2
- ZNF808 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs1289630044; called by muse, mutect2, varscan2
- ZNF827 | c.2669G>A p.G890E | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.122); catalogued as COSV65231973; called by muse, mutect2, varscan2
- ZNF860 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV64384455; called by muse, mutect2, varscan2
- ZSCAN18 | c.1034C>G p.S345C | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs1388204633, COSV99067332; called by muse, mutect2, varscan2
- ZSCAN5B | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1341260803; called by muse, varscan2
- AATK | c.3514G>C p.D1172H (on ENST00000326724 / NM_001080395.3; = p.D1069H on NM_004920.2) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCB4 | c.2447G>A p.R816K | Missense Mutation (SNP) | VAF 69/552 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 118/528 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- AC006059.2 | c.360G>T p.L120F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACAD8 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ACE | c.3236G>C p.G1079A | Missense Mutation (SNP) | VAF 86/451 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ACSF2 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 48/279 reads (17%) | called by muse, mutect2, varscan2
- ADAM10 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ADAM9 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- ADAM9 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ADAMTS18 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 154/368 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ADAMTS4 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGB | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRB3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ADGRG6 | c.3311C>G p.S1104* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2
- ADRA1A | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ADRA1D | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AEBP1 | c.2094C>G p.I698M | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AFMID | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.187); called by muse, varscan2
- AGR3 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2
- AHNAK | c.6946G>A p.D2316N | Missense Mutation (SNP) | VAF 73/374 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AKAP11 | c.4552C>G p.H1518D | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- AKAP6 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKAP9 | c.7900G>C p.E2634Q (on ENST00000359028; = p.E2610Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKT3 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AMBRA1 | c.1886C>G p.S629C (on ENST00000458649 / NM_001367468.1; = p.S539C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- AMBRA1 | c.1234C>G p.P412A (on ENST00000458649 / NM_001367468.1; = p.P322A on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/387 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMBRA1 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- AMIGO2 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMOTL2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ANGEL2 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2
- ANK2 | c.10246G>C p.E3416Q | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKAR | c.1720C>G p.L574V | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, varscan2
- ANKRD28 | c.568A>T p.K190* | Nonsense Mutation (SNP) | VAF 59/111 reads (53%) | called by muse, mutect2, varscan2
- ANKRD33B | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, varscan2
- ANKRD65 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ANP32B | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- AP002748.5 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- APOB | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 55/385 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AQP7 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARC | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ARHGAP24 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ARHGAP28 | c.517G>C p.D173H (on ENST00000383472 / NM_001366230.1; = p.D14H on NM_001010000.3) | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARHGAP31 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ARHGAP31 | c.3923G>C p.R1308T | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ARHGEF18 | c.394G>C p.E132Q (on ENST00000359920 / NM_001130955.2; = p.E28Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARHGEF19 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ASAP2 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASH2L | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.009); called by muse, varscan2
- ATE1 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, varscan2
- ATRNL1 | c.1325G>A p.S442N | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, varscan2
- BAG6 | c.630G>C p.L210F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- BARHL2 | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BCAT1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BCR | c.2609G>C p.R870T | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BDP1 | c.3052G>C p.E1018Q | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BGN | c.972_983del p.F325_K328del | In Frame Del (DEL) | VAF 63/140 reads (45%) | called by mutect2, pindel, varscan2
- BHLHE40 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- BIN1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- BIRC6 | c.8804C>G p.S2935* | Nonsense Mutation (SNP) | VAF 41/242 reads (17%) | called by muse, mutect2, varscan2
- BMERB1 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BOD1L1 | c.6278G>A p.G2093E | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRDT | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRMS1L | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BRPF1 | c.2653G>C p.E885Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.527); called by muse, mutect2
- C15orf39 | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C15orf39 | c.2461C>G p.Q821E | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- C19orf38 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- C1orf105 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- C1orf56 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.273); called by muse, varscan2
- C20orf96 | c.124C>G p.P42A (on ENST00000360321 / NM_153269.3; = p.P41A on NM_080571.1) | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD4D | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- C2orf69 | c.824T>A p.F275Y | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- C4orf54 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C8A | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 107/468 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CACNA1C | c.5718G>C p.E1906D (on ENST00000399634 / NM_001167625.1; = p.E1835D on NM_000719.7) | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1F | c.5910G>C p.E1970D | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CACNA1G | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CACNA2D4 | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAMSAP1 | c.1967C>G p.S656* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.3198G>C p.K1066N | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CAPN10 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CAPN6 | c.1521G>A p.W507* | Nonsense Mutation (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CBR1 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- CBX5 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CCDC178 | c.675G>C p.L225F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- CCDC6 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCND2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCNL2 | c.814del p.E272Kfs*7 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | called by pindel, varscan2
- CCNL2 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- CD101 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- CD14 | c.1088G>C p.G363A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2
- CD14 | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD46 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPC | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP250 | c.3159G>C p.E1053D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CEP290 | c.7273G>T p.E2425* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | called by muse, varscan2
- CEP290 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CEP95 | c.1610C>G p.S537C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CGB2 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 26/397 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CHMP4C | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- CHST2 | c.1250A>T p.Q417L | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CHTF18 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- CLCF1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- CLEC4G | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- CLEC4M | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLSPN | c.2155C>G p.L719V | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CNTNAP2 | c.3436T>G p.F1146V | Missense Mutation (SNP) | VAF 188/610 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- COL4A2 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL5A3 | c.4877C>G p.S1626C | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- COPE | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COPS5 | c.179_204del p.L60Cfs*20 | Frame Shift Del (DEL) | VAF 66/272 reads (24%) | called by mutect2, pindel
- CORO1B | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPA5 | c.1039-7C>T | Splice Region (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- CPB1 | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CPLANE1 | c.9371C>T p.S3124L | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2
- CPSF3 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CREBRF | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, varscan2
- CSKMT | c.328C>G p.P110A | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CSRNP2 | c.1193C>G p.S398* | Nonsense Mutation (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- CTCFL | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, varscan2
- CTNND2 | c.3089G>A p.G1030E | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUEDC1 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 33/243 reads (14%) | called by muse, mutect2, varscan2
- CYLC2 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CYP26C1 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CYP4X1 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CYP4X1 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- DAB1 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- DARS2 | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 53/395 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- DBNDD1 | c.259G>A p.E87K (on ENST00000002501 / NM_001042610.3; = p.E107K on NM_024043.3) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF11 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- DDHD2 | c.1522C>G p.P508A | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX1 | c.1700G>C p.R567T | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- DDX1 | c.1988A>T p.E663V | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DDX46 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DENND2A | c.2920G>C p.E974Q | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- DENND2C | c.1456C>A p.Q486K (on ENST00000393274 / NM_001256404.2; = p.Q429K on NM_198459.4) | Missense Mutation (SNP) | VAF 112/294 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- DEPDC7 | c.517G>A p.D173N (on ENST00000241051 / NM_001077242.2; = p.D164N on NM_139160.2) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DICER1 | c.4628C>T p.S1543F | Missense Mutation (SNP) | VAF 99/501 reads (20%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- DIS3 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DISC1 | c.1847C>G p.S616* | Nonsense Mutation (SNP) | VAF 57/326 reads (17%) | called by muse, mutect2, varscan2
- DLGAP2 | c.470_471del p.S157* | Frame Shift Del (DEL) | VAF 116/261 reads (44%) | called by mutect2, pindel*, varscan2*
- DMXL1 | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- DMXL2 | c.6018dup p.D2007Rfs*2 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- DNAH10 | c.8252G>A p.R2751K (on ENST00000409039; = p.R2690K on NM_207437.3) | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DNAH14 | c.2404G>T p.E802* (on ENST00000445597; = p.E868* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- DNAH2 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH2 | c.13220G>T p.G4407V | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.4486C>G p.Q1496E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DNAH9 | c.4410G>T p.E1470D | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- DOCK5 | c.5324C>T p.S1775L | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPF2 | c.898_899delinsT p.R300Sfs*13 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | called by pindel, varscan2*
- DPP8 | c.2358C>G p.F786L (on ENST00000341861 / NM_001320875.2; = p.F670L on NM_017743.6) | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DPP8 | c.409G>T p.D137Y (on ENST00000341861 / NM_001320875.2; = p.D121Y on NM_017743.6) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DRD1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DSEL | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 40/205 reads (20%) | called by muse, mutect2, varscan2
- DSG4 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 75/394 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DYNC1LI1 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DZIP3 | c.3007dup p.L1003Pfs*26 | Frame Shift Ins (INS) | VAF 28/151 reads (19%) | called by mutect2, pindel, varscan2
- EGF | c.1816C>T p.H606Y | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EGLN3 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 60/345 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- EGR2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- EIF2AK3 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- EIF3M | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ELMO2 | c.1066-1G>C p.X356_splice | Splice Site (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- ELMO3 | c.484C>T p.P162S (on ENST00000652269; = p.P109S on NM_024712.5) | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMILIN1 | c.2878G>T p.E960* | Nonsense Mutation (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- EML4 | c.2710C>T p.Q904* | Nonsense Mutation (SNP) | VAF 76/370 reads (21%) | called by muse, mutect2, varscan2
- ENPP3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTPD3 | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- EP400 | c.1621G>T p.G541W | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERAP1 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ERLIN2 | c.555G>A p.L185= | Splice Region (SNP) | VAF 98/454 reads (22%) | called by muse, mutect2, varscan2
- EXD2 | c.1043C>T p.S348F (on ENST00000312994 / NM_001193362.1; = p.S223F on NM_018199.3) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- F5 | c.4588G>C p.E1530Q | Missense Mutation (SNP) | VAF 81/524 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FADS2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAM162A | c.264-1G>C p.X88_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- FAM184B | c.1608G>C p.L536F | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.242); called by muse, varscan2
- FAM186A | c.4591C>G p.L1531V | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, varscan2
- FAM186A | c.3479C>A p.T1160N | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM193A | c.2938G>C p.E980Q | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- FAM199X | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAM71D | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.403); called by muse, varscan2
- FASTKD5 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- FBLN1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, varscan2
- FBN2 | c.4663G>A p.E1555K | Missense Mutation (SNP) | VAF 72/447 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- FBN2 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 36/367 reads (10%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO11 | c.562G>T p.E188* (on ENST00000403359 / NM_001190274.2; = p.E104* on NM_025133.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/171 reads (23%) | called by muse, mutect2, varscan2
- FCRL4 | c.769G>T p.G257* | Nonsense Mutation (SNP) | VAF 234/405 reads (58%) | called by muse, mutect2, varscan2
- FER1L5 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- FGF18 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FIGN | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- FLNB | c.6424G>C p.E2142Q | Missense Mutation (SNP) | VAF 69/293 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- FMN2 | c.4384G>C p.E1462Q | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FNDC3B | c.1380-2A>G p.X460_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- FREM1 | c.4279G>C p.E1427Q | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FREM3 | c.5071G>A p.E1691K | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FRMD5 | c.1685C>G p.S562* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- FRY | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FRYL | c.5144C>G p.S1715C | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FSIP2 | c.14881C>G p.L4961V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- FUT11 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- FYTTD1 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- GABRA1 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GABRR3 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GALNT2 | c.713T>G p.L238R | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAREM2 | c.1845C>G p.F615L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBF1 | c.5075G>C p.G1692A (on ENST00000369983 / NM_001377137.1; = p.G1691A on NM_004193.3) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- GCC2 | c.2251C>G p.Q751E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GIMAP4 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- GNL3 | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, varscan2
- GOLGA3 | c.2550G>A p.V850= | Splice Region (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- GOLGA8M | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); called by mutect2, varscan2
- GPR137B | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR52 | c.879G>C p.L293F | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPR87 | c.234C>G p.F78L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- GREB1 | c.4090A>T p.R1364W | Missense Mutation (SNP) | VAF 138/259 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA3 | c.1953T>A p.N651K | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRIN3A | c.2009T>C p.M670T | Missense Mutation (SNP) | VAF 60/261 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- GRIN3A | c.1053A>C p.E351D | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM6 | c.1997C>G p.S666C | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HAUS3 | c.1633C>T p.L545F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- HDAC5 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- HDC | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 84/369 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDGF | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 85/585 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HDLBP | c.3034G>C p.E1012Q | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- HECTD2 | c.660del p.W220* | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- HELLS | c.795G>T p.M265I | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- HIBADH | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- HLA-B | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, varscan2
- HLF | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HMCN1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 63/508 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- HMCN2 | c.9175G>T p.V3059F | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- HMCN2 | c.12313G>C p.E4105Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- HMGXB4 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HNRNPL | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- HNRNPU | c.1786C>G p.L596V (on ENST00000283179; = p.L658V on NM_004501.3) | Missense Mutation (SNP) | VAF 72/489 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- HRC | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- HS6ST1 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 104/874 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, varscan2
- HSPA6 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- HSPD1 | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- HTATSF1 | c.1518G>C p.K506N | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- HYAL1 | c.1248C>G p.F416L | Missense Mutation (SNP) | VAF 69/369 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ICE1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2
- IFNGR1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IFT140 | c.1056G>T p.R352S | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGDCC4 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IGF2BP3 | c.1321-7G>C | Splice Region (SNP) | VAF 67/167 reads (40%) | called by muse, mutect2, varscan2
- IGF2BP3 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IKZF5 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IL27RA | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- IMMP1L | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- IMPG2 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- INAFM1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- INAVA | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ING3 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 57/477 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- INPP5D | c.916G>A p.E306K (on ENST00000445964 / NM_001017915.3; = p.E305K on NM_005541.5) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- INPP5D | c.1704G>T p.K568N (on ENST00000445964 / NM_001017915.3; = p.K567N on NM_005541.5) | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- INPP5J | c.2383G>A p.E795K (on ENST00000331075 / NM_001284285.2; = p.E427K on NM_001002837.2) | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- IPO9 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2
- IQGAP1 | c.1118C>G p.S373C | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, varscan2
- IQGAP3 | c.4771C>G p.L1591V | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQSEC3 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by mutect2, varscan2
- IRAK1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAK1BP1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ITGAX | c.585C>A p.N195K | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ITGB8 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 44/297 reads (15%) | called by muse, mutect2, varscan2
- ITPR1 | c.2577G>C p.E859D (on ENST00000354582; = p.E844D on NM_002222.7) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KANSL1 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KCNA6 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KCNK12 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM3A | c.3187G>A p.D1063N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KDM4B | c.2120C>G p.S707C | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- KDM5C | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIAA0100 | c.5411C>G p.S1804C | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1109 | c.11912C>T p.S3971L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KIF13B | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- KIF5C | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- KIRREL1 | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- KLF10 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- KLF16 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- KLHL21 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- KLHL31 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KLK1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KPNB1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- KRI1 | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- KRT26 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- KRTAP9-4 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 65/389 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- L1TD1 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by mutect2, varscan2
- LAMA2 | c.4776G>C p.M1592I | Missense Mutation (SNP) | VAF 82/400 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMB1 | c.3985C>G p.L1329V | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMB3 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 214/349 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- LAMB4 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC1 | c.3942G>A p.M1314I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAPTM4B | c.303C>G p.F101L (on ENST00000445593; = p.F10L on NM_018407.6) | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.164); called by muse, varscan2
- LCT | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 65/473 reads (14%) | called by muse, mutect2, varscan2
- LEF1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIFR | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- LIN52 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- LLGL2 | c.1795G>C p.E599Q | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- LLGL2 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- LMBRD2 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 34/268 reads (13%) | called by muse, varscan2
- LMOD1 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- LRATD2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- LRMDA | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- LRRC43 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, varscan2
- LRRC58 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, varscan2
- LTA4H | c.712-1G>T p.X238_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- LYST | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- MAGEA12 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAN2A2 | c.1194G>C p.E398D | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.072); called by muse, varscan2
- MAN2C1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MAN2C1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2
- MAP1A | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAP1S | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP3K1 | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MAPT | c.2209G>C p.D737H (on ENST00000262410 / NM_001377265.1; = p.D345H on NM_005910.5) | Missense Mutation (SNP) | VAF 66/441 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARF1 | c.1388G>C p.R463T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARK1 | c.1604C>A p.S535Y | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MARK4 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MDC1 | c.4322C>T p.S1441F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- MED12L | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MEMO1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.24); called by muse, varscan2
- MEP1B | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 38/249 reads (15%) | called by muse, mutect2, varscan2
- MERTK | c.1515C>G p.I505M | Missense Mutation (SNP) | VAF 104/706 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.38); called by muse, varscan2
- MERTK | c.1542G>C p.L514F | Missense Mutation (SNP) | VAF 95/628 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, varscan2
- METTL15 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- METTL27 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- METTL2A | c.1092G>A p.W364* | Nonsense Mutation (SNP) | VAF 57/316 reads (18%) | called by muse, mutect2, varscan2
- MIEN1 | c.21G>C p.Q7H | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MMP20 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 70/593 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
843 further variants in this file (297 protein-altering or splice-affecting, 358 silent, 188 other) are not listed here.
